Gene-level copy-number profile of tumor specimen TCGA-XE-AANI-01A from TCGA case TCGA-XE-AANI, project TCGA-TGCT (Testicular Germ Cell Tumors). Sex at birth: male; Vital status: Alive; Primary diagnosis: Teratocarcinoma; Tissue or organ of origin: Testis, NOS; AJCC pathologic stage: Stage IS; Age at diagnosis: 37.1 years (13,553 days).
Specimen TCGA-XE-AANI-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-TGCT.10914ae7-68c9-41f6-b977-6d8e8f9f52de.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-XE-AANI-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 808 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/6d8246ca-254a-4107-aee8-c6aa262af68e

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 230; copy number 2: 18,831; copy number 3: 34,268; copy number 4: 5,334; copy number 6: 209; copy number 8: 943.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-XE-AANI-01A-11D-A434-01): tumor purity 0.81, ploidy 2.86, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 943 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:53,493,523–57,805,029, 79 genes, copy number 8 (broad region; genes not listed).
- chr12:66,767–38,589,812, 864 genes, copy number 8 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 230. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
